Somatic mutation profile of tumor specimen MP2PRT-PAVWAY-TMP1-A (aliquot MP2PRT-PAVWAY-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVWAY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.3 years (1,948 days).
Specimen MP2PRT-PAVWAY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f980e14f-ac01-483a-8574-145088261f7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWAY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWAY-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d678682-5701-4d1d-8a08-4fa95e564834

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 16, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 91/419 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CAPG | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 140/558 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs774144382, COSV99809552; called by muse, mutect2, varscan2
- CBLN3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 93/541 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs905850443; called by muse, mutect2, varscan2
- CCDC93 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 115/479 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs1230812804; called by muse, mutect2, varscan2
- ETV3 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 143/569 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs540027756; called by muse, mutect2, varscan2
- FAH | c.42C>G p.I14M | Missense Mutation (SNP) | VAF 108/535 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99930085; called by muse, mutect2, varscan2
- FRMPD3 | c.3779G>A p.R1260H | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs778726589, COSV52191461; called by muse, mutect2
- KIAA0232 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs1265983984; called by muse, mutect2, varscan2
- KLHL1 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as rs566153616; called by muse, mutect2, varscan2
- PTPRH | c.2129C>G p.S710C | Missense Mutation (SNP) | VAF 24/775 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99059254; called by muse, mutect2
- TMC3 | c.2992G>C p.E998Q | Missense Mutation (SNP) | VAF 129/598 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV63924296; called by muse, mutect2, varscan2
- ZNF48 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 157/735 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs781069579; called by muse, mutect2, varscan2
- ADAM7 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- AMOTL2 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 23/672 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2
- BTNL9 | c.468C>A p.D156E | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH6 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CEMIP | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 94/455 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEP170 | c.2743G>C p.D915H | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP68 | c.1972C>G p.L658V | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- COQ5 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DELE1 | c.720C>G p.F240L | Missense Mutation (SNP) | VAF 104/422 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FRRS1 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 58/251 reads (23%) | called by muse, mutect2, varscan2
- FSCN3 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 81/435 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- KMT2C | c.14671G>C p.E4891Q | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MED25 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 189/816 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PGC | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 128/523 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLA2 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF175 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 76/411 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- APC2 | c.75G>C p.L25= | Silent (SNP) | VAF 107/521 reads (21%) | called by muse, mutect2, varscan2
- CEP295 | c.7578G>A p.V2526= | Silent (SNP) | VAF 69/368 reads (19%) | called by muse, mutect2, varscan2
- COL2A1 | c.3858G>C p.L1286= | Silent (SNP) | VAF 74/310 reads (24%) | called by muse, mutect2, varscan2
- DNAH1 | c.2112G>A p.V704= | Silent (SNP) | VAF 86/408 reads (21%) | called by muse, mutect2, varscan2
- ELMO2 | c.630G>A p.K210= | Silent (SNP) | VAF 76/366 reads (21%) | called by muse, mutect2, varscan2
- EML6 | c.2001C>G p.L667= | Silent (SNP) | VAF 63/338 reads (19%) | called by muse, mutect2, varscan2
- FOXN4 | c.939C>T p.S313= | Silent (SNP) | VAF 88/506 reads (17%) | called by muse, mutect2, varscan2
- MUC12 | c.13659G>A p.T4553= (on ENST00000379442; = p.T4410= on NM_001164462.1) | Silent (SNP) | VAF 156/2183 reads (7%) | catalogued as rs563691747; called by muse, mutect2
- OPLAH | c.3570G>A p.A1190= | Silent (SNP) | VAF 34/880 reads (4%) | called by muse, mutect2
- PALM3 | c.1974G>A p.E658= (on ENST00000340790; = p.E673= on NM_001145028.2) | Silent (SNP) | VAF 23/529 reads (4%) | called by muse, mutect2
- PCSK5 | c.1785C>G p.L595= | Silent (SNP) | VAF 83/362 reads (23%) | catalogued as rs1178892222; called by muse, mutect2, varscan2
- SLC4A3 | c.1065G>A p.T355= | Silent (SNP) | VAF 128/506 reads (25%) | catalogued as rs1234185753; called by muse, mutect2, varscan2
- TRPM6 | c.975C>G p.L325= | Silent (SNP) | VAF 79/433 reads (18%) | called by muse, mutect2, varscan2
- ZNF175 | c.699C>T p.F233= | Silent (SNP) | VAF 59/313 reads (19%) | catalogued as rs1236607980, COSV51795036; called by muse, mutect2, varscan2
- ZNF175 | c.966C>G p.L322= | Silent (SNP) | VAF 85/331 reads (26%) | catalogued as COSV99219633; called by muse, mutect2, varscan2
- ZNF454 | c.723G>A p.E241= | Silent (SNP) | VAF 104/444 reads (23%) | called by muse, mutect2, varscan2
- ARCN1 | c.3+1184G>A | Intron (SNP) | VAF 70/377 reads (19%) | called by muse, mutect2, varscan2
